Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7716, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7716-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description	Microscopic Description	Diagnosis Details
		BR-7716			

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Stomach

Tumor size: 6 x 6 x 1.5 cm

Tumor features: None
specified

Histologic type:

Adenocarcinoma

Histologic grade: Moderately
differentiated

Tumor extent: Adjacent
structures (specify) - Lesser
omentum

Lymph nodes: 1/4 positive for
metastasis (Intraabdominal
1/4)

Lymphatic invasion: Not
specified

Venous invasion: Not specified

Perineural invasion: Not
specified

Margins: Not specified

Evidence of neo-adjuvant
treatment: Not specified

Additional pathologic findings:
Not specified

Comments: None

Date of Procurement

Source: NCI Genomic Data Commons file dd5ac1f9-d924-4fd6-9d80-2bf6428d4754 (TCGA-BR-7716.6E595D32-0A21-4EF3-B76F-4A9C6E35D044.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).